Somatic mutation profile of tumor specimen C3L-03965-02 (aliquot CPT0207210006) from CPTAC case C3L-03965, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 54.1 years (19,760 days).
Specimen C3L-03965-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16422f85-f3d3-4725-8015-282167d690e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03965-31 (Blood Derived Normal), aliquot CPT0207360002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bafb310b-8c43-4af6-ab4c-9a6b265c1acf

The open-access MAF lists 539 somatic variants for this specimen: 375 protein-altering or splice-affecting, 108 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 311, Silent 108, Intron 31, Nonsense Mutation 19, Splice Site 17, Frame Shift Del 13, 5'Flank 8, In Frame Del 8, RNA 7, Splice Region 5, 3'UTR 5, 5'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.7568dup p.K2524Efs*15 | Frame Shift Ins (INS) | VAF 74/202 reads (37%) | catalogued as rs1566242125; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 372/698 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as rs1057520005, COSV52707923, COSV52708386, COSV52728497, COSV53727597; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTSL3 | c.5072G>A p.G1691E | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs750201654; called by muse, mutect2, varscan2
- ALPK3 | c.2278C>A p.P760T | Missense Mutation (SNP) | VAF 67/191 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs36007548; called by muse, mutect2, varscan2
- ANKRD20A4P | c.725A>G p.H242R | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1231047432; called by mutect2, varscan2
- ANKRD35 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as rs782234906; called by muse, mutect2
- ANPEP | c.1434C>A p.S478R | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as rs371398651; called by muse, mutect2, varscan2
- ASB3 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as rs771292908; called by muse, mutect2
- ATP13A4 | c.794T>C p.V265A | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as rs1366447008; called by muse, mutect2, varscan2
- BIRC6 | c.4193G>A p.R1398Q | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV70197441; called by muse, mutect2, varscan2
- C16orf90 | c.178G>A p.G60R (on ENST00000399645 / NM_001353385.2; = p.G51R on NM_001080524.2) | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.148); catalogued as rs747753694; called by muse, mutect2, varscan2
- CARM1 | c.1670C>T p.T557M | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1404227792; called by muse, mutect2, varscan2
- CASKIN1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 72/278 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs371614946; called by muse, varscan2
- CCDC136 | c.1070C>T p.T357I | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1388106421; called by muse, mutect2, varscan2
- CCDC38 | c.1485-2A>T p.X495_splice | Splice Site (SNP) | VAF 33/226 reads (15%) | catalogued as rs778911969; called by muse, mutect2, varscan2
- CCN4 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 36/502 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs139602125; called by muse, mutect2
- CD1C | c.281G>C p.G94A | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV100939360; called by muse, mutect2, varscan2
- COL15A1 | c.1205C>A p.P402Q | Missense Mutation (SNP) | VAF 169/379 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.094); catalogued as COSV100897613; called by muse, mutect2, varscan2
- COL1A2 | c.892-1G>T p.X298_splice | Splice Site (SNP) | VAF 165/577 reads (29%) | catalogued as COSV51956846; called by muse, mutect2, varscan2
- CSMD1 | c.7889C>A p.P2630Q (on ENST00000520002; = p.P2629Q on NM_033225.6) | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV59386908; called by muse, mutect2, varscan2
- CSMD3 | c.3345A>T p.E1115D (on ENST00000297405 / NM_001363185.1; = p.E1011D on NM_052900.3) | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV52172460; called by muse, mutect2, varscan2
- CSNK2A3 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 69/329 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV57145092; called by muse, mutect2, varscan2
- DBT | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 76/517 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.335); catalogued as rs766456499; called by muse, mutect2, varscan2
- DCT | c.1456C>G p.L486V | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs141419278; called by muse, mutect2, varscan2
- DISP2 | c.489G>C p.Q163H | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs200805831; called by muse, mutect2, varscan2
- DNAH11 | c.7186G>A p.D2396N | Missense Mutation (SNP) | VAF 76/284 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1267150542; called by muse, mutect2, varscan2
- ECM1 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 46/303 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as COSV60873960; called by muse, mutect2, varscan2
- ELP4 | c.1172C>G p.S391* (on ENST00000350638; = p.S390* on NM_019040.5) | Nonsense Mutation (SNP) | VAF 43/181 reads (24%) | catalogued as COSV63353980; called by muse, mutect2, varscan2
- EMX2 | c.311C>A p.S104* | Nonsense Mutation (SNP) | VAF 59/266 reads (22%) | catalogued as COSV101463611; called by muse, mutect2, varscan2
- ENTPD8 | c.674G>A p.S225N | Missense Mutation (SNP) | VAF 67/438 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1564247012; called by muse, mutect2, varscan2
- EPB41L4A | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs773785227; called by muse, mutect2, varscan2
- ERBB4 | c.1964C>G p.A655G | Missense Mutation (SNP) | VAF 101/482 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99621226; called by muse, mutect2, varscan2
- FAAH | c.131C>A p.A44E | Missense Mutation (SNP) | VAF 87/189 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1243477522; called by muse, mutect2, varscan2
- FABP1 | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55557758, COSV55558121; called by muse, mutect2, varscan2
- FAM205A | c.3766C>G p.P1256A | Missense Mutation (SNP) | VAF 133/497 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); catalogued as COSV66488466; called by muse, mutect2, varscan2
- FAM47C | c.1141del p.E381Nfs*444 | Frame Shift Del (DEL) | VAF 59/191 reads (31%) | catalogued as COSV63728377; called by mutect2, pindel, varscan2
- FASTKD2 | c.1431G>T p.Q477H | Missense Mutation (SNP) | VAF 60/586 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.5); catalogued as rs371052365; called by muse, mutect2
- FBXO40 | c.1279G>C p.A427P | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100572961; called by muse, mutect2, varscan2
- FBXW7 | c.1922C>T p.S641L (on ENST00000281708 / NM_001349798.2; = p.S561L on NM_018315.5) | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55906561, COSV55910110; called by muse, mutect2, varscan2
- FCER2 | c.841G>T p.V281L | Missense Mutation (SNP) | VAF 282/723 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV100689682; called by muse, mutect2, varscan2
- FGD3 | c.2086G>T p.E696* | Nonsense Mutation (SNP) | VAF 44/343 reads (13%) | catalogued as COSV100490534; called by muse, mutect2, varscan2
- FHL3 | c.764C>G p.S255C | Missense Mutation (SNP) | VAF 52/352 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as rs896708881; called by muse, varscan2
- FREM3 | c.2032G>A p.D678N | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61681844; called by muse, mutect2, varscan2
- FSIP2 | c.17350G>T p.A5784S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs774274371, COSV58096699; called by muse, mutect2, varscan2
- GAD1 | c.1592G>C p.R531P | Missense Mutation (SNP) | VAF 98/503 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV64025155, COSV64025272; called by muse, mutect2, varscan2
- GBE1 | c.1237G>C p.D413H | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752711257, CM143606, COSV101450114; called by muse, mutect2, varscan2
- GNA15 | c.766G>C p.A256P | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99505299; called by muse, mutect2, varscan2
- GPR68 | c.1002G>C p.Q334H | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV53175596; called by muse, mutect2, varscan2
- GREB1 | c.2798A>G p.Q933R | Missense Mutation (SNP) | VAF 222/561 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs765576941; called by muse, mutect2, varscan2
- GRIN2A | c.55C>A p.R19S | Missense Mutation (SNP) | VAF 152/374 reads (41%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.019); catalogued as COSV100408696, COSV58045915; called by muse, mutect2, varscan2
- GTF3C2 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 53/405 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs768291859; called by muse, mutect2, varscan2
- HPS3 | c.46G>T p.V16L | Missense Mutation (SNP) | VAF 90/229 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs1194897511; called by muse, mutect2, varscan2
- IFNA2 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 103/258 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476058261; called by muse, mutect2, varscan2
- IGHV1-46 | c.19G>T p.V7F | Missense Mutation (SNP) | VAF 156/328 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs556133466; called by muse, mutect2, varscan2
- IRS2 | c.3077C>T p.S1026L | Missense Mutation (SNP) | VAF 91/162 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as rs1211275740; called by muse, mutect2, varscan2
- JUP | c.1976A>G p.D659G | Missense Mutation (SNP) | VAF 129/903 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs782124059; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM5A | c.3031A>G p.I1011V | Missense Mutation (SNP) | VAF 106/470 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.627); catalogued as rs1270014289; called by muse, mutect2, varscan2
- KIF23 | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT tolerated (0.89); PolyPhen benign (0.125); catalogued as rs1303479679; called by muse, mutect2, varscan2
- KLF17 | c.573G>C p.L191F | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs778395622; called by muse, mutect2, varscan2
- KRT5 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 99/408 reads (24%) | catalogued as CM021625, COSV99357931; called by muse, mutect2, varscan2
- KRTAP1-5 | c.245A>T p.Q82L | Missense Mutation (SNP) | VAF 138/1149 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV62624366; called by muse, mutect2, varscan2
- LAG3 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 167/502 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs748975660, COSV52569672; called by muse, mutect2, varscan2
- LRP1B | c.3425C>A p.P1142H | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs772545514, COSV101261534; called by muse, mutect2, varscan2
- LRRC4C | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as rs746822718; called by muse, mutect2, varscan2
- MMP16 | c.995G>T p.R332I | Missense Mutation (SNP) | VAF 99/353 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV54155058; called by muse, mutect2, varscan2
- MMP9 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs976680437; called by muse, mutect2, varscan2
- MPV17 | c.279+3G>A | Splice Region (SNP) | VAF 113/541 reads (21%) | catalogued as rs1263647718; called by muse, mutect2, varscan2
- MUC12 | c.9044C>G p.T3015S (on ENST00000379442; = p.T2872S on NM_001164462.1) | Missense Mutation (SNP) | VAF 190/2726 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.913); catalogued as rs1431052005, COSV65206780; called by muse, mutect2
- MUC16 | c.39401G>C p.G13134A | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV66695521; called by muse, mutect2
- MYO18A | c.1677C>G p.I559M | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV62865542; called by muse, mutect2, varscan2
- NALCN | c.1369C>T p.L457F | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV51925096; called by muse, mutect2, varscan2
- NLRC3 | c.277G>C p.V93L | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as rs751476980; called by muse, mutect2, varscan2
- NOL4L | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1034437430; called by muse, mutect2, varscan2
- NPAP1 | c.1571del p.P524Lfs*7 | Frame Shift Del (DEL) | VAF 51/205 reads (25%) | catalogued as COSV61509982; called by mutect2, pindel, varscan2
- NXPH1 | c.408G>C p.L136F | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68317734; called by muse, mutect2, varscan2
- ODF1 | c.443T>A p.V148E | Missense Mutation (SNP) | VAF 141/579 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53431673; called by muse, mutect2, varscan2
- OLFM3 | c.312C>G p.N104K (on ENST00000338858 / NM_001288821.1; = p.N84K on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.538); catalogued as COSV58795679; called by muse, mutect2
- OR10AG1 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs762004398, COSV56631509; called by muse, mutect2, varscan2
- OR2M3 | c.120G>T p.M40I | Missense Mutation (SNP) | VAF 75/270 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV101513419; called by muse, mutect2, varscan2
- OR4N2 | c.744C>A p.F248L | Missense Mutation (SNP) | VAF 288/1122 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV60052119, COSV60053155; called by mutect2, varscan2
- OR52W1 | c.93G>A p.W31* | Nonsense Mutation (SNP) | VAF 52/234 reads (22%) | catalogued as rs1268407651; called by muse, mutect2, varscan2
- OR6C4 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 107/384 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as rs867905154; called by muse, mutect2, varscan2
- OSBPL11 | c.1959G>C p.L653F | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.892); catalogued as COSV99953855; called by muse, mutect2, varscan2
- PARP15 | c.1714C>T p.H572Y (on ENST00000464300 / NM_001113523.3; = p.H338Y on NM_152615.2) | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs778870087; called by muse, mutect2
- PCSK5 | c.1739G>A p.R580K | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100949447; called by muse, mutect2, varscan2
- PDZRN3 | c.2994C>A p.S998R | Missense Mutation (SNP) | VAF 93/200 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747504737, COSV55197783; called by muse, mutect2, varscan2
- PIK3C2A | c.4093G>A p.A1365T | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs191488721; called by muse, mutect2, varscan2
- PKD1 | c.8503C>A p.P2835T | Missense Mutation (SNP) | VAF 188/880 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99237689; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1021C>A p.H341N | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV65047221, COSV65049756; called by muse, mutect2, varscan2
- PNPT1 | c.2064A>T p.E688D | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as rs780574835; called by muse, mutect2, varscan2
- PTBP2 | c.118A>T p.M40L (on ENST00000426398 / NM_001300986.2; = p.M32L on NM_021190.4) | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV64624735; called by muse, mutect2, varscan2
- PTPN4 | c.235A>G p.T79A | Missense Mutation (SNP) | VAF 84/201 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.02); catalogued as rs773010444, COSV55303059; called by muse, mutect2, varscan2
- RADX | c.1641A>C p.Q547H | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.187); catalogued as COSV100998689; called by muse, mutect2, varscan2
- RAPH1 | c.213A>G p.I71M | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1354679548; called by muse, mutect2, varscan2
- RND2 | c.76G>A p.V26M | Missense Mutation (SNP) | VAF 123/370 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330516244; called by muse, mutect2, varscan2
- SEMA6B | c.1738+3G>A | Splice Region (SNP) | VAF 35/85 reads (41%) | catalogued as rs868624927; called by muse, mutect2, varscan2
- SERPINI1 | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99854839; called by muse, mutect2, varscan2
- SGCD | c.94C>G p.R32G (on ENST00000435422 / NM_001128209.2; = p.R33G on NM_000337.5) | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM105576, COSV61910963; called by muse, mutect2, varscan2
- SLCO1C1 | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs199727951; called by muse, mutect2, varscan2
- SMPDL3A | c.550A>G p.I184V | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs1218538809, COSV63755114; called by muse, mutect2, varscan2
- STPG2 | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54821261; called by muse, mutect2, varscan2
- STUM | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as rs1326129901; called by muse, mutect2, varscan2
- TBCCD1 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 209/732 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs979450897, COSV58661966; called by muse, mutect2, varscan2
- TEAD1 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 111/486 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100532780; called by muse, mutect2, varscan2
- TELO2 | c.2338A>T p.S780C | Missense Mutation (SNP) | VAF 52/289 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51980210; called by muse, mutect2, varscan2
- TLR7 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs1299955214, COSV101028205; called by mutect2, varscan2
- TOX2 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 71/320 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.048); catalogued as COSV57886257; called by muse, mutect2, varscan2
- TRABD2A | c.920G>T p.R307I (on ENST00000409520 / NM_001277053.2; = p.R258I on NM_001080824.3) | Missense Mutation (SNP) | VAF 94/291 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100119592; called by muse, mutect2, varscan2
- TRAV27 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1277084719; called by muse, mutect2, varscan2
- TRGV11 | c.222T>G p.N74K | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as rs530504796; called by muse, mutect2, varscan2
- TRIM39 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 206/564 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.338); catalogued as COSV100935918, COSV64955688; called by muse, mutect2, varscan2
- TRMT5 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 97/254 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.327); catalogued as rs1171115457; called by muse, mutect2, varscan2
- TRPC7 | c.1597C>A p.P533T | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as rs1232863025; called by muse, mutect2, varscan2
- TSHZ2 | c.1052A>G p.N351S | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs771963472; called by muse, mutect2, varscan2
- TTN | c.40784C>G p.A13595G (on ENST00000591111; = p.A6171G on NM_003319.4) | Missense Mutation (SNP) | VAF 59/448 reads (13%) | PolyPhen benign (0.273); catalogued as COSV100625906; called by muse, mutect2, varscan2
- TYW1B | c.1482C>G p.D494E | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs782627197; called by muse, mutect2, varscan2
- UNC80 | c.4879G>A p.D1627N | Missense Mutation (SNP) | VAF 72/331 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.536); catalogued as rs967601478, COSV55888910; called by muse, mutect2, varscan2
- UPK3B | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.279); catalogued as rs758910902; called by muse, mutect2, varscan2
- USH2A | c.7853G>T p.W2618L | Missense Mutation (SNP) | VAF 58/303 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as CM165986, COSV100241181; called by muse, mutect2, varscan2
- VWA5B2 | c.3511G>A p.V1171I | Missense Mutation (SNP) | VAF 22/301 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs1031389086; called by muse, mutect2
- WASHC2C | c.81G>C p.E27D | Missense Mutation (SNP) | VAF 150/774 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV60491032; called by muse, varscan2
- XIRP2 | c.7811G>T p.R2604I (on ENST00000628543; = p.R2779I on NM_152381.6) | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.246); catalogued as COSV54739678; called by muse, mutect2, varscan2
- ZBTB21 | c.1816C>G p.P606A | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.656); catalogued as rs751551584, COSV100176993; called by muse, mutect2, varscan2
- ZC3H6 | c.1175C>G p.P392R | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1371781116; called by muse, mutect2, varscan2
- ZDHHC5 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); catalogued as rs766835263, COSV54705436; called by muse, mutect2, varscan2
- ZMAT4 | c.586C>A p.R196S | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.027); catalogued as COSV52701716, COSV52713141; called by muse, mutect2, varscan2
- ZNF202 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as rs375244404; called by muse, mutect2, varscan2
- ZNF507 | c.2477C>A p.A826E | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100321770, COSV61332958; called by muse, mutect2, varscan2
- ZZEF1 | c.6944C>T p.S2315F | Missense Mutation (SNP) | VAF 72/484 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV67558536; called by muse, mutect2, varscan2
- ACBD5 | c.157C>T p.Q53* (on ENST00000375888 / NM_001352568.1; = p.Q55* on NM_145698.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 68/304 reads (22%) | called by muse, mutect2, varscan2
- ACTN4 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 108/475 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ADAMTS18 | c.1408G>T p.G470* | Nonsense Mutation (SNP) | VAF 58/292 reads (20%) | called by muse, mutect2, varscan2
- ADGRE2 | c.350G>A p.C117Y | Missense Mutation (SNP) | VAF 35/340 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRG2 | c.2610A>C p.L870F (on ENST00000379869 / NM_001079858.3; = p.L867F on NM_005756.4) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ADPRH | c.159_162del p.S54Tfs*4 | Frame Shift Del (DEL) | VAF 41/293 reads (14%) | called by mutect2, pindel, varscan2
- AGTR1 | c.526A>G p.N176D | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ALG10 | c.1228C>G p.Q410E | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANKRD53 | c.1158G>T p.W386C | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APBA3 | c.618G>A p.V206= | Splice Region (SNP) | VAF 46/411 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.474+1G>T p.X158_splice | Splice Site (SNP) | VAF 16/154 reads (10%) | called by muse, mutect2
- ATG2A | c.4604C>A p.S1535Y | Missense Mutation (SNP) | VAF 76/525 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP6V0A2 | c.2255C>T p.S752F | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BBX | c.2472G>T p.K824N (on ENST00000325805 / NM_001142568.3; = p.K794N on NM_020235.7) | Missense Mutation (SNP) | VAF 81/472 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BICDL2 | c.1359+1G>A p.X453_splice | Splice Site (SNP) | VAF 43/288 reads (15%) | called by muse, mutect2, varscan2
- C1orf194 | c.126A>T p.E42D (on ENST00000369948 / NM_001245025.3; = p.E30D on NM_001122961.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/278 reads (14%) | SIFT tolerated (0.99); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C2orf42 | c.1637A>T p.N546I | Missense Mutation (SNP) | VAF 130/686 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C5AR1 | c.643_667delinsTT p.L215Ffs*103 | Frame Shift Del (DEL) | VAF 39/158 reads (25%) | called by pindel, varscan2*
- CCDC168 | c.12972C>A p.S4324R | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT tolerated (0.51); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CCDC172 | c.46C>G p.Q16E | Missense Mutation (SNP) | VAF 69/379 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CCDC178 | c.1206A>T p.Q402H | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCDC83 | c.1008G>C p.E336D (on ENST00000342404 / NM_001286159.2; = p.E367D on NM_173556.5) | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- CCT8L2 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDH2 | c.1325G>A p.G442E | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDKN2A | c.102_119del p.G35_A40del | In Frame Del (DEL) | VAF 99/240 reads (41%) | called by mutect2, pindel, varscan2
- CELA3A | c.796-2A>G p.X266_splice | Splice Site (SNP) | VAF 90/302 reads (30%) | called by muse, mutect2, varscan2
- CEP295NL | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 108/368 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- CFAP126 | c.397A>C p.K133Q | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- CLEC9A | c.98G>A p.C33Y | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLIC5 | c.911T>A p.L304Q (on ENST00000185206 / NM_001370649.1; = p.L145Q on NM_016929.5) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CLIP2 | c.815G>T p.C272F | Missense Mutation (SNP) | VAF 53/315 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTFR | c.1060G>T p.V354F | Missense Mutation (SNP) | VAF 159/615 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- CNTNAP2 | c.2378G>A p.G793E | Missense Mutation (SNP) | VAF 71/555 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL14A1 | c.5212_5223del p.R1738_P1741del | In Frame Del (DEL) | VAF 15/169 reads (9%) | called by mutect2, pindel
- CPEB3 | c.1543G>T p.V515L | Missense Mutation (SNP) | VAF 64/283 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPXM1 | c.1478_1484del p.L493Pfs*16 | Frame Shift Del (DEL) | VAF 46/234 reads (20%) | called by mutect2, pindel, varscan2
- CRAMP1 | c.877A>C p.M293L | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- CSMD3 | c.6757G>T p.G2253* (on ENST00000297405 / NM_001363185.1; = p.G2149* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 38/259 reads (15%) | called by muse, mutect2, varscan2
- CTAG2 | c.305C>A p.A102E | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CUL3 | c.2110G>C p.E704Q | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CXCL2 | c.85A>T p.S29C | Missense Mutation (SNP) | VAF 39/278 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- CYP39A1 | c.332_349del p.V111_H116del | In Frame Del (DEL) | VAF 22/203 reads (11%) | called by mutect2, pindel
- DACT2 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 63/243 reads (26%) | called by muse, mutect2, varscan2
- DDX20 | c.1988C>T p.T663I | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DDX60 | c.3301C>T p.P1101S | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- DGKG | c.765G>T p.L255F | Missense Mutation (SNP) | VAF 30/503 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- DHX29 | c.2489G>T p.S830I | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DIDO1 | c.5917C>A p.H1973N | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2
- DIDO1 | c.5915T>A p.V1972D | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.799); called by muse, mutect2
- DISP3 | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 108/296 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DNAH14 | c.7588C>T p.H2530Y (on ENST00000445597; = p.H3302Y on NM_001367479.1) | Missense Mutation (SNP) | VAF 85/440 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- DNAH17 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 95/297 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DNAH8 | c.1657C>A p.Q553K | Missense Mutation (SNP) | VAF 86/250 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DPYS | c.349T>A p.W117R | Missense Mutation (SNP) | VAF 89/447 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DUSP8 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 44/174 reads (25%) | called by muse, mutect2, varscan2
- EFCAB5 | c.2417G>A p.R806K | Missense Mutation (SNP) | VAF 94/308 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- EIF2B1 | c.409G>C p.V137L | Missense Mutation (SNP) | VAF 77/400 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EIF4A3 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 42/332 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ELAVL2 | c.97A>T p.N33Y | Missense Mutation (SNP) | VAF 59/288 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ELOVL2 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- ENAH | c.1537A>C p.R513= | Splice Region (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- ENTPD6 | c.1271A>T p.Q424L | Missense Mutation (SNP) | VAF 96/270 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EPG5 | c.6613A>T p.K2205* | Nonsense Mutation (SNP) | VAF 53/101 reads (52%) | called by muse, mutect2, varscan2
- EPOR | c.827+1G>A p.X276_splice | Splice Site (SNP) | VAF 45/268 reads (17%) | called by muse, mutect2, varscan2
- ERICH3 | c.3717G>T p.Q1239H | Missense Mutation (SNP) | VAF 105/221 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- FADS2 | c.146G>A p.W49* | Nonsense Mutation (SNP) | VAF 87/301 reads (29%) | called by muse, mutect2, varscan2
- FAM171A2 | c.544_558del p.Q182_R186del | In Frame Del (DEL) | VAF 44/271 reads (16%) | called by mutect2, pindel, varscan2
- FAM178B | c.1559G>A p.S520N | Missense Mutation (SNP) | VAF 73/297 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- FAT4 | c.2814C>A p.N938K | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- FAT4 | c.5957G>T p.G1986V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FBN3 | c.7889G>A p.G2630D | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- FBN3 | c.2612_2621del p.N871Sfs*27 | Frame Shift Del (DEL) | VAF 54/348 reads (16%) | called by mutect2, pindel, varscan2
- FGF12 | c.485C>A p.T162K (on ENST00000454309 / NM_021032.5; = p.T100K on NM_004113.6) | Missense Mutation (SNP) | VAF 75/305 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- FLG | c.9935G>T p.S3312I | Missense Mutation (SNP) | VAF 111/678 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXG1 | c.1277T>C p.M426T | Missense Mutation (SNP) | VAF 188/649 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- FOXP1 | c.1544_1555del p.H515_S518del | In Frame Del (DEL) | VAF 24/163 reads (15%) | called by mutect2, pindel, varscan2
- FREM1 | c.1937G>T p.G646V | Missense Mutation (SNP) | VAF 102/182 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FSIP2 | c.8969A>G p.Q2990R | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAL3ST3 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- GAS2L1 | c.256_279del p.A86_V93del | In Frame Del (DEL) | VAF 27/155 reads (17%) | called by mutect2, pindel
- GBA2 | c.1993C>T p.L665F | Missense Mutation (SNP) | VAF 49/405 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GML | c.451A>T p.I151F | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- GPNMB | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPR6 | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- GXYLT2 | c.582_600+8del p.X194_splice | Splice Site (DEL) | VAF 18/70 reads (26%) | called by mutect2, pindel
- HDAC4 | c.2873A>C p.K958T | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- HIF1AN | c.178-1G>A p.X60_splice | Splice Site (SNP) | VAF 31/67 reads (46%) | called by muse, mutect2, varscan2
- HNRNPA1L2 | c.855C>A p.S285R | Missense Mutation (SNP) | VAF 59/393 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXA2 | c.233C>A p.A78E | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HSD17B6 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2
- HTR1B | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 34/329 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.962); called by muse, mutect2
- HTT | c.2752G>A p.D918N | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IFT80 | c.1537G>T p.A513S | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IGF2R | c.414+1G>A p.X138_splice | Splice Site (SNP) | VAF 26/98 reads (27%) | called by muse, mutect2, varscan2
- IGLV3-16 | c.176G>C p.G59A | Missense Mutation (SNP) | VAF 84/533 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- IHH | c.408C>A p.D136E | Missense Mutation (SNP) | VAF 63/328 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IMPG1 | c.1414C>A p.Q472K | Missense Mutation (SNP) | VAF 55/422 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ITGA2 | c.698A>T p.E233V | Missense Mutation (SNP) | VAF 133/296 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- JUP | c.1975G>T p.D659Y | Missense Mutation (SNP) | VAF 131/902 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KCNMA1 | c.3734A>G p.D1245G (on ENST00000404771; = p.R1181= on NM_001014797.3) | Missense Mutation (SNP) | VAF 126/304 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KIAA1109 | c.10670+1G>T p.X3557_splice | Splice Site (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2
- KIAA1755 | c.1087C>A p.H363N | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF4B | c.1922G>T p.W641L | Missense Mutation (SNP) | VAF 222/407 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL11 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- KRT78 | c.1048-1G>T p.X350_splice | Splice Site (SNP) | VAF 30/202 reads (15%) | called by muse, mutect2
- LAMC1 | c.2450G>C p.G817A | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMO7 | c.1971G>A p.W657* (on ENST00000357063; = p.W387* on NM_015842.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/176 reads (22%) | called by muse, mutect2, varscan2
- LOXHD1 | c.1345A>C p.I449L | Missense Mutation (SNP) | VAF 53/346 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MADD | c.1654G>C p.G552R | Missense Mutation (SNP) | VAF 94/398 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAP1A | c.1367_1384del p.L456_K461del | In Frame Del (DEL) | VAF 52/494 reads (11%) | called by mutect2, pindel
- MATN2 | c.252G>T p.L84F | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCOLN1 | c.491_504del p.A164Vfs*15 | Frame Shift Del (DEL) | VAF 114/1077 reads (11%) | called by mutect2, pindel
- MCTP2 | c.1100A>G p.N367S | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- MEGF6 | c.3191_3204del p.P1064Rfs*5 | Frame Shift Del (DEL) | VAF 47/171 reads (27%) | called by mutect2, pindel, varscan2
- MFSD6L | c.997C>G p.L333V | Missense Mutation (SNP) | VAF 122/218 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- MLH3 | c.2059C>T p.P687S | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MLYCD | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 63/261 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- MMD2 | c.520A>C p.T174P | Missense Mutation (SNP) | VAF 120/331 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- MORC1 | c.2749C>A p.L917M | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MROH2A | c.4331G>T p.S1444I | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MUC5B | c.5776C>A p.P1926T | Missense Mutation (SNP) | VAF 97/478 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NAPRT | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- NCKAP5 | c.5366A>G p.H1789R | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCOA2 | c.2478G>T p.R826S | Missense Mutation (SNP) | VAF 80/513 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- NCOA6 | c.4534G>T p.D1512Y | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEBL | c.944A>T p.Y315F | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- NKD1 | c.907A>C p.I303L | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NPFF | c.37C>G p.L13V | Missense Mutation (SNP) | VAF 117/404 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- NR6A1 | c.1211G>T p.G404V (on ENST00000487099 / NM_033334.4; = p.G399V on NM_001489.5) | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.969); called by muse, varscan2
- OR10X1 | c.613T>G p.C205G | Missense Mutation (SNP) | VAF 51/306 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2J2 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 108/200 reads (54%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.945); called by mutect2, varscan2
- OR6C4 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 106/373 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- OR6K2 | c.63G>T p.W21C | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- OVCH1 | c.228G>T p.L76F | Missense Mutation (SNP) | VAF 75/309 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAPPA2 | c.1918G>T p.D640Y | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.11617C>G p.Q3873E | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- PCNX2 | c.2972C>T p.S991F | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PDE11A | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PDE4B | c.827C>G p.S276* | Nonsense Mutation (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- PHF20 | c.742_761del p.S248Gfs*41 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | called by mutect2, pindel
- PIGO | c.2971G>T p.E991* | Nonsense Mutation (SNP) | VAF 51/391 reads (13%) | called by muse, mutect2, varscan2
- PIK3C2A | c.2320A>C p.S774R | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- PIWIL1 | c.1072A>G p.K358E | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKP2 | c.1295A>G p.E432G | Missense Mutation (SNP) | VAF 275/705 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PLD5 | c.642del p.Y214* (on ENST00000442594; = p.Y152* on NM_001195811.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 68/263 reads (26%) | called by mutect2, pindel, varscan2
- PLD5 | c.607G>T p.G203* (on ENST00000442594; = p.G141* on NM_001195811.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 48/158 reads (30%) | called by muse, varscan2
- PLD5 | c.312C>G p.C104W (on ENST00000442594; = p.C42W on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLIN5 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 63/439 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- POU3F3 | c.428C>A p.P143Q | Missense Mutation (SNP) | VAF 71/219 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPFIBP2 | c.2191G>C p.D731H | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP4R3C | c.2290C>A p.P764T | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- PRR14 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- PRUNE2 | c.5674C>A p.Q1892K | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PXDNL | c.4148T>C p.I1383T | Missense Mutation (SNP) | VAF 93/227 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- RFWD3 | c.1817G>T p.G606V | Missense Mutation (SNP) | VAF 78/408 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RHOB | c.251T>G p.F84C | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIMKLA | c.685+2T>A p.X229_splice | Splice Site (SNP) | VAF 43/110 reads (39%) | called by muse, mutect2, varscan2
- RNPC3 | c.192G>A p.L64= | Splice Region (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2
- ROBO3 | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPAP3 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- SALL1 | c.2371G>A p.G791S | Missense Mutation (SNP) | VAF 101/297 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- SCML4 | c.260G>T p.S87I | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SENP6 | c.2832T>G p.S944R | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SFMBT1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- SIPA1L3 | c.776G>C p.G259A | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC16A13 | c.12G>C p.R4S | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SLC35F1 | c.809A>T p.H270L | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- SLC4A2 | c.1367G>T p.G456V | Missense Mutation (SNP) | VAF 88/237 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC5A12 | c.593C>A p.T198K | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- SLC6A7 | c.933_937del p.Y312Hfs*8 | Frame Shift Del (DEL) | VAF 18/163 reads (11%) | called by mutect2, pindel, varscan2
- SLC8A3 | c.1350G>C p.E450D | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- SLC9B2 | c.1033G>C p.G345R | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLCO5A1 | c.1594G>T p.G532W | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLITRK5 | c.1203C>G p.I401M | Missense Mutation (SNP) | VAF 127/240 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- SLTM | c.1088C>A p.T363K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SMCHD1 | c.5587G>C p.D1863H | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- SORCS3 | c.1212+1G>A p.X404_splice | Splice Site (SNP) | VAF 45/88 reads (51%) | called by muse, mutect2, varscan2
- SORT1 | c.1606G>T p.A536S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX17 | c.402C>A p.N134K | Missense Mutation (SNP) | VAF 77/268 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SP8 | c.1253G>T p.C418F (on ENST00000361443 / NM_198956.4; = p.C436F on NM_182700.6) | Missense Mutation (SNP) | VAF 113/713 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA13 | c.717G>C p.Q239H | Missense Mutation (SNP) | VAF 115/247 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- SPATA31A1 | c.1381A>G p.T461A | Missense Mutation (SNP) | VAF 203/1143 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.26); called by mutect2, varscan2
- SPATA31A6 | c.1097T>G p.L366W | Missense Mutation (SNP) | VAF 134/972 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SPATA31E1 | c.3085G>C p.A1029P | Missense Mutation (SNP) | VAF 127/352 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- STAT1 | c.834A>T p.K278N | Missense Mutation (SNP) | VAF 173/693 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- STAT2 | c.1959G>T p.E653D | Missense Mutation (SNP) | VAF 14/425 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2
- STKLD1 | c.1676G>C p.R559T | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3028T>A p.C1010S | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- STXBP4 | c.1456G>C p.V486L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STXBP5L | c.2953G>A p.V985M | Missense Mutation (SNP) | VAF 135/400 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SUZ12 | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SYT8 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- TAF2 | c.1717G>T p.G573* | Nonsense Mutation (SNP) | VAF 81/224 reads (36%) | called by muse, mutect2, varscan2
- TAGLN3 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 48/303 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCEA1 | c.152A>G p.N51S | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TDRD6 | c.3670C>T p.L1224F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- TECPR1 | c.2283G>T p.M761I | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TECPR1 | c.66_75del p.Q23Kfs*64 | Frame Shift Del (DEL) | VAF 40/404 reads (10%) | called by mutect2, pindel
- TEF | c.872C>A p.T291N | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TG | c.7585A>T p.S2529C | Missense Mutation (SNP) | VAF 188/659 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TGS1 | c.1498G>C p.E500Q | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); called by muse, mutect2
- THBS2 | c.1331C>G p.S444* | Nonsense Mutation (SNP) | VAF 74/353 reads (21%) | called by muse, mutect2, varscan2
- TIAM1 | c.1703A>T p.K568I | Missense Mutation (SNP) | VAF 149/336 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- TLR4 | c.2270G>T p.W757L (on ENST00000355622 / NM_138554.5; = p.W717L on NM_003266.4) | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TMEM216 | c.229+1G>C p.X77_splice (on ENST00000515837 / NM_001173990.3; = p.X16_splice on NM_016499.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 26/161 reads (16%) | called by muse, mutect2, varscan2
- TMEM30B | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- TMEM65 | c.74C>A p.A25E | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- TMEM68 | c.172-2A>G p.X58_splice | Splice Site (SNP) | VAF 52/158 reads (33%) | called by mutect2, varscan2
- TRPC3 | c.1735C>A p.Q579K (on ENST00000379645 / NM_001366479.2; = p.Q506K on NM_003305.2) | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TTN | c.49613C>A p.T16538N (on ENST00000591111; = p.T9114N on NM_003319.4) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | PolyPhen benign (0.107); called by muse, mutect2, varscan2
- TTN | c.45893C>A p.P15298Q (on ENST00000591111; = p.P7874Q on NM_003319.4) | Missense Mutation (SNP) | VAF 160/725 reads (22%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUT4 | c.4184T>C p.V1395A | Missense Mutation (SNP) | VAF 49/279 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TUT4 | c.2261A>C p.E754A | Missense Mutation (SNP) | VAF 15/487 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2
- UBQLN1 | c.1745G>C p.R582T | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UGT2B11 | c.1109C>G p.A370G | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- UGT2B11 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- UNC5D | c.2537C>A p.T846N | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- USP13 | c.2399A>T p.K800M | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- USP48 | c.675G>C p.Q225H | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- USP5 | c.238-1G>C p.X80_splice | Splice Site (SNP) | VAF 34/152 reads (22%) | called by muse, mutect2, varscan2
- UTRN | c.4945-1G>C p.X1649_splice | Splice Site (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2
- VNN2 | c.1208C>G p.T403R | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- VWA1 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- WASHC2A | c.81G>C p.E27D | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2
- WDR64 | c.2370G>T p.E790D | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WDR64 | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- WDR91 | c.808A>T p.K270* | Nonsense Mutation (SNP) | VAF 59/288 reads (20%) | called by muse, mutect2, varscan2
- WDR97 | c.2399C>A p.T800N | Missense Mutation (SNP) | VAF 415/756 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WNK1 | c.3136G>T p.A1046S (on ENST00000315939 / NM_018979.4; = p.A799S on NM_014823.3) | Missense Mutation (SNP) | VAF 89/470 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WNK3 | c.4292C>T p.S1431F | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XIRP1 | c.2452C>G p.R818G | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- XIRP2 | c.9560A>G p.H3187R (on ENST00000628543; = p.H3362R on NM_152381.6) | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XPO7 | c.1655G>A p.S552N | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- YTHDF3 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ZC4H2 | c.43A>G p.K15E | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZDHHC14 | c.905A>T p.Y302F | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZHX3 | c.1773_1787del p.A592_T596del | In Frame Del (DEL) | VAF 24/130 reads (18%) | called by mutect2, pindel, varscan2
- ZMYM1 | c.2099A>T p.Y700F | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- ZNF646 | c.3602G>T p.R1201L | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF704 | c.1188G>A p.M396I | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF717 | c.2678T>A p.I893K | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- ZNF717 | c.2676T>A p.H892Q | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2
- ZNF717 | c.1943T>C p.V648A | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- ZNF726 | c.686A>T p.Y229F | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- ZNF799 | c.1362del p.A456Pfs*64 | Frame Shift Del (DEL) | VAF 109/449 reads (24%) | called by mutect2, varscan2
- ZNF804B | c.3986C>T p.S1329F | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- AATK | c.2925C>T p.P975= (on ENST00000326724 / NM_001080395.3; = p.P872= on NM_004920.2) | Silent (SNP) | VAF 27/412 reads (7%) | catalogued as COSV58363675; called by muse, mutect2
- ABCA13 | c.5598C>A p.P1866= | Silent (SNP) | VAF 38/179 reads (21%) | called by muse, mutect2, varscan2
- ABCA7 | c.5856G>A p.P1952= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as rs1362550289; called by muse, mutect2, varscan2
- ABCC2 | c.924C>T p.S308= | Silent (SNP) | VAF 69/303 reads (23%) | called by muse, mutect2, varscan2
- AC005833.1 | c.1413C>G p.L471= | Silent (SNP) | VAF 61/181 reads (34%) | catalogued as rs1166702771; called by muse, mutect2, varscan2
- ACOT12 | c.534A>C p.T178= | Silent (SNP) | VAF 54/122 reads (44%) | catalogued as COSV56894566; called by muse, mutect2, varscan2
- ADNP2 | c.3135A>G p.K1045= | Silent (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- AIPL1 | c.354G>T p.V118= | Silent (SNP) | VAF 175/329 reads (53%) | called by muse, mutect2, varscan2
- AJM1 | c.1023C>G p.S341= | Silent (SNP) | VAF 71/392 reads (18%) | called by muse, mutect2, varscan2
- AKAP9 | c.8820A>T p.T2940= (on ENST00000359028; = p.T2916= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/314 reads (16%) | catalogued as rs1042092642; called by muse, mutect2, varscan2
- ANKRD31 | c.3615A>G p.V1205= | Silent (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- ANO1 | c.1191G>A p.T397= | Silent (SNP) | VAF 55/448 reads (12%) | catalogued as rs374133844; called by muse, mutect2, varscan2
- ARMCX4 | c.327G>A p.Q109= (on ENST00000433011; = p.Q5= on NM_001256155.2) | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs1556007561; called by muse, mutect2, varscan2
- BMPR1A | c.471C>T p.L157= | Silent (SNP) | VAF 141/350 reads (40%) | catalogued as rs1060504903; ClinVar: likely benign; called by muse, mutect2, varscan2
- BRD4 | c.468C>T p.L156= | Silent (SNP) | VAF 34/303 reads (11%) | catalogued as COSV54584563; called by muse, mutect2, varscan2
- C11orf96 | c.267G>A p.K89= | Silent (SNP) | VAF 38/167 reads (23%) | called by muse, mutect2, varscan2
- CA14 | c.477C>G p.V159= | Silent (SNP) | VAF 31/283 reads (11%) | called by muse, mutect2, varscan2
- CASKIN1 | c.480C>A p.R160= | Silent (SNP) | VAF 71/276 reads (26%) | catalogued as COSV58878374; called by muse, varscan2
- CCDC71L | c.696G>T p.V232= | Silent (SNP) | VAF 82/303 reads (27%) | called by muse, mutect2, varscan2
- CDKAL1 | c.528G>C p.V176= | Silent (SNP) | VAF 44/88 reads (50%) | called by muse, mutect2, varscan2
- CFAP54 | c.4378C>T p.L1460= | Silent (SNP) | VAF 56/185 reads (30%) | called by muse, mutect2, varscan2
- CSNK2A2 | c.603A>G p.P201= | Silent (SNP) | VAF 48/304 reads (16%) | called by muse, mutect2, varscan2
- CXCR1 | c.756G>T p.L252= | Silent (SNP) | VAF 30/176 reads (17%) | called by muse, mutect2, varscan2
- CYP11B1 | c.1038C>T p.A346= | Silent (SNP) | VAF 150/380 reads (39%) | catalogued as rs776234575; ClinVar: likely benign; called by muse, mutect2, varscan2
- DCAF8L2 | c.1248G>T p.L416= | Silent (SNP) | VAF 32/112 reads (29%) | called by muse, mutect2, varscan2
- DEF6 | c.783G>A p.P261= | Silent (SNP) | VAF 131/250 reads (52%) | catalogued as rs377414352; called by muse, mutect2, varscan2
- DENND5B | c.312T>A p.I104= | Silent (SNP) | VAF 14/252 reads (6%) | called by muse, mutect2
- DHX37 | c.699C>T p.P233= | Silent (SNP) | VAF 48/288 reads (17%) | catalogued as rs368071109, COSV58131379; called by muse, mutect2, varscan2
- DMWD | c.1413G>C p.P471= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV52181084; called by muse, mutect2, varscan2
- DNAH7 | c.6858C>T p.I2286= | Silent (SNP) | VAF 26/232 reads (11%) | catalogued as rs771896188, COSV100415626, COSV56765911; called by muse, mutect2, varscan2
- DNAJB9 | c.429A>T p.T143= | Silent (SNP) | VAF 32/269 reads (12%) | called by muse, mutect2, varscan2
- DPP10 | c.213G>A p.L71= | Silent (SNP) | VAF 27/186 reads (15%) | catalogued as COSV100067295; called by muse, mutect2, varscan2
- DSCAM | c.2805C>A p.T935= | Silent (SNP) | VAF 86/196 reads (44%) | called by muse, mutect2, varscan2
- DSCAM | c.2166G>T p.V722= | Silent (SNP) | VAF 42/112 reads (38%) | called by muse, mutect2, varscan2
- FAT4 | c.2815C>T p.L939= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as rs1479723271; called by muse, mutect2, varscan2
- FAT4 | c.11244T>A p.T3748= | Silent (SNP) | VAF 8/135 reads (6%) | called by muse, mutect2
- FBLN2 | c.2136G>T p.A712= | Silent (SNP) | VAF 27/144 reads (19%) | catalogued as COSV55491886; called by muse, mutect2, varscan2
- FLII | c.3066G>A p.T1022= | Silent (SNP) | VAF 43/231 reads (19%) | catalogued as rs372936022; called by muse, mutect2, varscan2
- FMN2 | c.1173C>A p.A391= | Silent (SNP) | VAF 65/101 reads (64%) | called by muse, mutect2, varscan2
- FNDC11 | c.15G>A p.V5= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV64442627; called by muse, mutect2
- GRIA2 | c.2112G>T p.V704= | Silent (SNP) | VAF 98/237 reads (41%) | catalogued as COSV52395840; called by muse, mutect2, varscan2
- HENMT1 | c.453G>T p.G151= | Silent (SNP) | VAF 19/172 reads (11%) | catalogued as rs768742983; called by muse, mutect2
- HERC2 | c.5436C>A p.A1812= | Silent (SNP) | VAF 72/548 reads (13%) | catalogued as rs983059798; called by muse, mutect2, varscan2
- HSPB6 | c.438C>T p.A146= | Silent (SNP) | VAF 34/120 reads (28%) | called by muse, mutect2, varscan2
- IGLV3-16 | c.177C>T p.G59= | Silent (SNP) | VAF 85/531 reads (16%) | called by muse, mutect2, varscan2
- KIAA1217 | c.549T>A p.S183= | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2
- KLHL12 | c.78C>G p.L26= | Silent (SNP) | VAF 65/367 reads (18%) | catalogued as COSV66125010; called by muse, mutect2, varscan2
- KRTAP5-1 | c.648C>T p.S216= | Silent (SNP) | VAF 94/422 reads (22%) | called by muse, mutect2, varscan2
- LCOR | c.483G>A p.E161= | Silent (SNP) | VAF 81/193 reads (42%) | catalogued as rs1268649077; called by muse, mutect2, varscan2
- LRRC4C | c.190C>A p.R64= | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as COSV53421139, COSV53435466; called by muse, mutect2, varscan2
- LYN | c.354G>T p.V118= | Silent (SNP) | VAF 48/185 reads (26%) | called by muse, mutect2, varscan2
- MAP3K9 | c.2742G>A p.R914= (on ENST00000554752 / NM_001284230.1; = p.R928= on NM_033141.4) | Silent (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- MCCC1 | c.525A>T p.V175= | Silent (SNP) | VAF 119/1051 reads (11%) | called by muse, mutect2, varscan2
- MRGPRX3 | c.444C>T p.A148= | Silent (SNP) | VAF 71/322 reads (22%) | catalogued as rs1386531238; called by muse, mutect2, varscan2
- MS4A14 | c.297C>A p.T99= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV55738941; called by muse, mutect2
- MYF6 | c.42C>T p.Y14= | Silent (SNP) | VAF 32/189 reads (17%) | called by muse, mutect2, varscan2
- NDUFB9 | c.81C>T p.L27= | Silent (SNP) | VAF 220/857 reads (26%) | called by muse, mutect2, varscan2
- NEK10 | c.2067G>T p.V689= | Silent (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2
- NFRKB | c.1224G>A p.S408= (on ENST00000446488 / NM_001143835.2; = p.S433= on NM_006165.3) | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as rs767378140, COSV58760121; called by muse, mutect2, varscan2
- NR1I2 | c.1200C>A p.L400= | Silent (SNP) | VAF 237/670 reads (35%) | called by muse, mutect2, varscan2
- NR4A2 | c.1047G>A p.P349= | Silent (SNP) | VAF 56/396 reads (14%) | catalogued as rs749000269; called by muse, mutect2, varscan2
- OR1J1 | c.912C>G p.L304= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV52240014; called by muse, mutect2, varscan2
- OR7A10 | c.231T>A p.T77= | Silent (SNP) | VAF 36/389 reads (9%) | called by muse, mutect2
- PANK2 | c.513G>C p.S171= | Silent (SNP) | VAF 68/407 reads (17%) | called by muse, mutect2, varscan2
- PAPPA | c.9C>T p.L3= | Silent (SNP) | VAF 43/333 reads (13%) | called by muse, mutect2, varscan2
- PARM1 | c.285G>A p.S95= | Silent (SNP) | VAF 80/415 reads (19%) | catalogued as rs755092882, COSV56649891, COSV56650245; called by muse, mutect2, varscan2
- PCDHA8 | c.1479G>T p.S493= | Silent (SNP) | VAF 336/747 reads (45%) | called by muse, mutect2, varscan2
- PDE3A | c.375G>T p.R125= | Silent (SNP) | VAF 163/322 reads (51%) | called by muse, mutect2, varscan2
- PGM1 | c.1515C>T p.S505= | Silent (SNP) | VAF 178/400 reads (45%) | catalogued as rs61760978; ClinVar: likely benign; called by muse, mutect2, varscan2
- PIGA | c.417C>A p.L139= | Silent (SNP) | VAF 35/73 reads (48%) | called by muse, mutect2, varscan2
- PLB1 | c.1176C>T p.N392= | Silent (SNP) | VAF 51/459 reads (11%) | catalogued as rs147698393; called by muse, mutect2, varscan2
- PLBD1 | c.240C>T p.G80= | Silent (SNP) | VAF 81/450 reads (18%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2841C>T p.D947= | Silent (SNP) | VAF 140/371 reads (38%) | called by muse, mutect2, varscan2
- RESF1 | c.1302T>C p.Y434= | Silent (SNP) | VAF 14/248 reads (6%) | catalogued as rs762677765; called by muse, mutect2
- RFX2 | c.1410G>A p.L470= | Silent (SNP) | VAF 93/347 reads (27%) | called by muse, mutect2, varscan2
- RGS9 | c.1032C>T p.S344= | Silent (SNP) | VAF 52/501 reads (10%) | called by muse, mutect2, varscan2
- RPS6 | c.402C>G p.G134= | Silent (SNP) | VAF 96/350 reads (27%) | called by muse, varscan2
- RRP8 | c.1005G>A p.L335= | Silent (SNP) | VAF 47/225 reads (21%) | called by muse, mutect2, varscan2
- RYR2 | c.11022A>T p.T3674= | Silent (SNP) | VAF 29/90 reads (32%) | called by muse, mutect2, varscan2
- SETD2 | c.1116C>T p.D372= | Silent (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2, varscan2
- SFMBT2 | c.948C>T p.Y316= | Silent (SNP) | VAF 40/147 reads (27%) | catalogued as rs1426443140; called by muse, mutect2, varscan2
- SLAMF6 | c.849T>A p.T283= (on ENST00000368057 / NM_001184714.2; = p.T282= on NM_052931.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/212 reads (12%) | called by muse, mutect2, varscan2
- SOX14 | c.615C>A p.T205= | Silent (SNP) | VAF 26/164 reads (16%) | called by muse, mutect2, varscan2
- SP9 | c.858C>T p.A286= | Silent (SNP) | VAF 23/376 reads (6%) | catalogued as rs1352021733; called by muse, mutect2
- SPATA31E1 | c.636T>A p.P212= | Silent (SNP) | VAF 59/160 reads (37%) | called by muse, mutect2, varscan2
- SPTA1 | c.4047G>A p.E1349= | Silent (SNP) | VAF 32/198 reads (16%) | called by muse, mutect2, varscan2
- SRCAP | c.3264C>T p.S1088= | Silent (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- STAP2 | c.379C>T p.L127= | Silent (SNP) | VAF 72/318 reads (23%) | catalogued as rs1485731249; called by muse, mutect2, varscan2
- STX7 | c.429A>T p.V143= | Silent (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- SUCNR1 | c.237G>A p.L79= | Silent (SNP) | VAF 29/167 reads (17%) | called by muse, mutect2, varscan2
- SYNE1 | c.11307G>A p.E3769= (on ENST00000367255 / NM_182961.4; = p.E3754= on NM_033071.3) | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV55084396; called by muse, mutect2, varscan2
- SYNJ2 | c.405C>T p.N135= | Silent (SNP) | VAF 60/295 reads (20%) | catalogued as rs765515889; called by muse, mutect2, varscan2
- TBC1D15 | c.1695C>A p.L565= | Silent (SNP) | VAF 17/145 reads (12%) | called by muse, mutect2, varscan2
- TCF20 | c.501C>T p.Y167= | Silent (SNP) | VAF 65/340 reads (19%) | called by muse, varscan2
- TECRL | c.477C>T p.L159= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV67090266; called by muse, mutect2, varscan2
- TGIF2LX | c.420G>T p.A140= | Silent (SNP) | VAF 139/325 reads (43%) | catalogued as COSV52213290, COSV52213984; called by muse, mutect2, varscan2
- TIMM23 | c.63C>G p.A21= | Silent (SNP) | VAF 41/261 reads (16%) | catalogued as rs781848805; called by muse, mutect2, varscan2
- TMC2 | c.2664T>A p.S888= | Silent (SNP) | VAF 57/263 reads (22%) | called by muse, mutect2, varscan2
- TMPO | c.129G>A p.Q43= | Silent (SNP) | VAF 81/653 reads (12%) | called by muse, mutect2, varscan2
- TOP2A | c.1053A>G p.V351= | Silent (SNP) | VAF 73/234 reads (31%) | catalogued as rs1472578461; called by muse, mutect2, varscan2
- TSR1 | c.1440G>A p.L480= | Silent (SNP) | VAF 165/322 reads (51%) | called by muse, mutect2, varscan2
- UTP18 | c.783C>T p.P261= | Silent (SNP) | VAF 116/342 reads (34%) | catalogued as rs756629212, COSV56584224, COSV99834779; called by muse, mutect2, varscan2
- VSTM2B | c.684C>A p.T228= | Silent (SNP) | VAF 98/491 reads (20%) | called by muse, mutect2, varscan2
- WDR54 | c.978G>A p.A326= | Silent (SNP) | VAF 47/279 reads (17%) | catalogued as rs774437589, COSV51962164; called by muse, mutect2, varscan2
- WIZ | c.2959C>A p.R987= (on ENST00000673675 / NM_001371589.1; = p.R164= on NM_001330395.4) | Silent (SNP) | VAF 22/248 reads (9%) | called by muse, mutect2
- Z83844.2 | c.555G>T p.L185= | Silent (SNP) | VAF 47/302 reads (16%) | called by muse, mutect2, varscan2
- ZNF208 | c.2220G>A p.K740= | Silent (SNP) | VAF 42/384 reads (11%) | catalogued as COSV101237097; called by muse, varscan2
- ZNF425 | c.1482G>A p.R494= | Silent (SNP) | VAF 45/100 reads (45%) | catalogued as rs778530751; called by muse, mutect2, varscan2
- ACACB | c.6497-377A>G | Intron (SNP) | VAF 50/268 reads (19%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.3186+20G>A | Intron (SNP) | VAF 32/231 reads (14%) | called by muse, mutect2, varscan2
- AL162726.3 | n.255+83270G>T | Intron (SNP) | VAF 247/792 reads (31%) | called by muse, mutect2, varscan2
- ANK2 | c.84+57116T>G | Intron (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.1452C>T | RNA (SNP) | VAF 24/182 reads (13%) | catalogued as rs535171652; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504069 C>G | 5'Flank (SNP) | VAF 9/87 reads (10%) | catalogued as rs141917157; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504672 T>C | 5'Flank (SNP) | VAF 43/160 reads (27%) | called by muse, mutect2, varscan2
- ARHGAP1 | c.229+48C>T | Intron (SNP) | VAF 131/580 reads (23%) | catalogued as rs1168138892; called by muse, mutect2, varscan2
- ASXL3 | c.-22G>C | 5'UTR (SNP) | VAF 47/87 reads (54%) | called by muse, mutect2, varscan2
- BACE1 | chr11:117316443 C>A | 5'Flank (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- BCLAF1 | c.2220-69T>C | Intron (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- CLRN1 | c.*179G>T | 3'UTR (SNP) | VAF 31/155 reads (20%) | called by muse, mutect2, varscan2
- COL18A1-AS2 | chr21:45405239 G>T | 3'Flank (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- DAAM2 | c.*2297C>G | 3'UTR (SNP) | VAF 93/166 reads (56%) | called by muse, mutect2, varscan2
- DARS2 | c.*47T>C | 3'UTR (SNP) | VAF 27/134 reads (20%) | called by muse, mutect2, varscan2
- GABRG2 | c.1249-15C>T | Intron (SNP) | VAF 124/225 reads (55%) | catalogued as rs764389038; called by muse, mutect2, varscan2
- ITPR2 | c.5554+163G>A | Intron (SNP) | VAF 67/636 reads (11%) | catalogued as rs762553317; called by muse, mutect2, varscan2
- KCNK16 | c.803-209C>A | Intron (SNP) | VAF 70/419 reads (17%) | called by muse, mutect2, varscan2
- KDM5B | c.4021+34A>T | Intron (SNP) | VAF 39/146 reads (27%) | called by muse, mutect2, varscan2
- KRT10 | c.1374-47C>A | Intron (SNP) | VAF 116/388 reads (30%) | catalogued as rs1178253615, COSV99510107; called by muse, mutect2, varscan2
- KRT7 | chr12:52252468 T>C | 3'Flank (SNP) | VAF 94/399 reads (24%) | called by muse, varscan2
- LRRK2 | c.*24G>T | 3'UTR (SNP) | VAF 15/71 reads (21%) | called by muse, mutect2, varscan2
- MASP1 | c.1304-4877T>A | Intron (SNP) | VAF 180/547 reads (33%) | called by muse, mutect2, varscan2
- MED13L | c.5589-40C>A | Intron (SNP) | VAF 40/221 reads (18%) | called by muse, mutect2, varscan2
- MLIP | c.613-10849T>C | Intron (SNP) | VAF 113/285 reads (40%) | called by muse, mutect2, varscan2
- MYH6 | c.1581+14C>T | Intron (SNP) | VAF 77/669 reads (12%) | catalogued as rs548266405; called by muse, mutect2, varscan2
- NCSTN | c.190+21G>C | Intron (SNP) | VAF 66/421 reads (16%) | called by muse, mutect2, varscan2
- OR6W1P | n.383C>T | RNA (SNP) | VAF 15/137 reads (11%) | catalogued as rs774681213; called by muse, mutect2, varscan2
- PAICS | c.-52+9C>T | Intron (SNP) | VAF 145/298 reads (49%) | called by muse, mutect2, varscan2
- PDE7B | c.83-70399C>A | Intron (SNP) | VAF 104/434 reads (24%) | called by muse, mutect2, varscan2
- PET100 | c.-29_-11del | 5'UTR (DEL) | VAF 18/172 reads (10%) | called by mutect2, pindel
- POTEM | c.811-1231C>A | Intron (SNP) | VAF 108/652 reads (17%) | catalogued as rs1183377136; called by muse, varscan2
- POU2F2 | c.1401-10_1401-9dup | Intron (INS) | VAF 18/40 reads (45%) | catalogued as rs756588716; called by mutect2, varscan2
- PPFIBP1 | c.-36+21240C>T | Intron (SNP) | VAF 61/264 reads (23%) | catalogued as rs745679378; called by muse, mutect2, varscan2
- PRPF40B | chr12:49623514 C>A | 5'Flank (SNP) | VAF 12/62 reads (19%) | catalogued as rs1016981328; called by muse, mutect2
- PSEN2 | c.357-20C>T | Intron (SNP) | VAF 32/138 reads (23%) | called by muse, varscan2
- RAB26 | c.307-418T>A | Intron (SNP) | VAF 33/123 reads (27%) | catalogued as rs1407315531; called by muse, mutect2, varscan2
- RAB34 | c.-92G>C | 5'UTR (SNP) | VAF 71/215 reads (33%) | called by muse, mutect2, varscan2
- RIN1 | c.*22A>G | 3'UTR (SNP) | VAF 16/167 reads (10%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34158823 C>A | 5'Flank (SNP) | VAF 37/172 reads (22%) | catalogued as rs1040033846; called by muse, mutect2, varscan2
- ROGDI | c.531+48G>T | Intron (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-51636A>T | Intron (SNP) | VAF 28/160 reads (18%) | called by muse, mutect2, varscan2
- SNORD115-1 | n.61C>A | RNA (SNP) | VAF 102/402 reads (25%) | called by muse, varscan2
- SNORD115-36 | n.39G>C | RNA (SNP) | VAF 65/315 reads (21%) | called by muse, mutect2, varscan2
- SNORD116-12 | n.92C>G | RNA (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- SPATA31C1 | n.1646C>T | RNA (SNP) | VAF 107/722 reads (15%) | called by muse, mutect2, varscan2
- SRI | c.52-46A>G | Intron (SNP) | VAF 44/293 reads (15%) | called by muse, mutect2, varscan2
- STMN4 | c.110-431A>G | Intron (SNP) | VAF 34/119 reads (29%) | called by muse, mutect2, varscan2
- TAF8 | chr6:42048649 G>T | 5'Flank (SNP) | VAF 77/538 reads (14%) | called by muse, mutect2, varscan2
- TBC1D1 | c.2050+6312G>T | Intron (SNP) | VAF 31/94 reads (33%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2719+1141G>T | Intron (SNP) | VAF 40/192 reads (21%) | called by muse, mutect2, varscan2
- TRPA1 | c.1529+35C>A | Intron (SNP) | VAF 14/93 reads (15%) | catalogued as rs1460531614; called by muse, mutect2, varscan2
- TUBB7P | n.213C>T | RNA (SNP) | VAF 87/494 reads (18%) | catalogued as rs778343453; called by muse, mutect2, varscan2
- UBE2V2 | chr8:48008428 G>T | 5'Flank (SNP) | VAF 168/359 reads (47%) | called by muse, mutect2, varscan2
- ULK1 | c.2327-56T>A | Intron (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- ZBTB37 | chr1:173864229 T>C | 5'Flank (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
